Somatic mutation profile of tumor specimen ALCH-AE0R-TTP1-A (aliquot ALCH-AE0R-TTP1-A-2-0-D-A582-36) from ALCHEMIST case ALCH-AE0R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.1 years (27,431 days).
Specimen ALCH-AE0R-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec49551b-69fc-42ed-918c-89c175457198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0R-NB1-A (Blood Derived Normal), aliquot ALCH-AE0R-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a7e8a0-5d0d-4701-b983-13e95394e53b

The open-access MAF lists 80 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 22, Nonsense Mutation 4, 5'UTR 2, Splice Site 2, RNA 1, 3'UTR 1, Intron 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 47/615 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- STK11 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786201090, CD044169, CM981870, COSV58820334, COSV58822715; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACLY | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59862145; called by muse, mutect2
- ATP9A | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs1393409567, COSV58772391; called by muse, mutect2
- BARX1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1400402143, COSV54159348; called by muse, mutect2, varscan2
- GPR45 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV51525412; called by muse, mutect2
- GRIN1 | c.1486_1488del p.K496del | In Frame Del (DEL) | VAF 33/276 reads (12%) | catalogued as rs1231157661; called by pindel, varscan2
- HERC1 | c.6988C>T p.R2330C | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1348089106, COSV71247320; called by muse, mutect2
- HYDIN | c.6655del p.A2219Qfs*6 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | catalogued as COSV59254390; called by mutect2, varscan2
- LDLRAD4 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.979); catalogued as COSV63341168; called by muse, mutect2
- MED12L | c.5716-1G>C p.X1906_splice | Splice Site (SNP) | VAF 8/147 reads (5%) | catalogued as COSV99851205; called by muse, mutect2
- MPDZ | c.5473G>T p.E1825* (on ENST00000319217 / NM_001330637.2; = p.E1796* on NM_003829.5) | Nonsense Mutation (SNP) | VAF 44/570 reads (8%) | catalogued as COSV59921234; called by muse, mutect2
- PAPPA2 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62774001, COSV62780066; called by muse, mutect2
- PCDHGB6 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV53959164; called by muse, mutect2
- SERPINA12 | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV57942945; called by muse, mutect2
- STX18 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 29/793 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV60372735; called by muse, mutect2
- TMEM132B | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 46/769 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100169810; called by muse, mutect2
- XIRP2 | c.1609G>T p.E537* (on ENST00000628543; = p.E712* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 10/282 reads (4%) | catalogued as rs1351237525, COSV54700170; called by muse, mutect2
- ZEB1 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 22/846 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV100314184; called by muse, mutect2
- ZHX2 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.216); catalogued as rs1307885974; called by muse, mutect2
- ZSCAN10 | c.892G>A p.G298R (on ENST00000252463; = p.G353R on NM_032805.3) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1187420282; called by muse, mutect2
- AKAP11 | c.1075T>G p.F359V | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANO10 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSNK1G3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 17/507 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- DYNC1H1 | c.1982A>G p.Y661C | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM124A | c.597C>G p.S199R (on ENST00000322475 / NM_001242312.2; = p.S235R on NM_145019.4) | Missense Mutation (SNP) | VAF 49/589 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2
- FKBP10 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- FLAD1 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 22/736 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FOXL1 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2
- HELZ | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 36/662 reads (5%) | called by muse, mutect2
- HERC2 | c.1861A>C p.T621P | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HOXB8 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); called by muse, mutect2
- JCAD | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 36/636 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRT75 | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 47/770 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- MRPL45 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 19/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC2 | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0); called by muse, mutect2
- NBN | c.584+1G>T p.X195_splice | Splice Site (SNP) | VAF 23/602 reads (4%) | called by muse, mutect2
- OR2AP1 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PCDHA8 | c.1449C>G p.D483E | Missense Mutation (SNP) | VAF 60/965 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNX1 | c.6832G>T p.A2278S | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); called by muse, mutect2
- PKD1 | c.11894G>T p.R3965L (on ENST00000262304 / NM_001009944.3; = p.R3964L on NM_000296.4) | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PRSS21 | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTH1R | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- RELN | c.3756G>T p.M1252I | Missense Mutation (SNP) | VAF 46/832 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- RLF | c.3601A>T p.R1201* | Nonsense Mutation (SNP) | VAF 18/361 reads (5%) | called by muse, mutect2
- SP3 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- SVIL | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2
- TFE3 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 31/391 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TSGA10 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.482); called by muse, mutect2
- WDFY4 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 23/820 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF385B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF511 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 36/603 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2
- ALDH1B1 | c.168G>T p.T56= | Silent (SNP) | VAF 21/255 reads (8%) | catalogued as COSV100890926; called by muse, mutect2
- APC2 | c.3198G>A p.S1066= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as rs1192571326; called by muse, mutect2
- BARHL2 | c.795G>T p.L265= | Silent (SNP) | VAF 23/411 reads (6%) | called by muse, mutect2
- BCL11A | c.1974G>A p.S658= (on ENST00000335712 / NM_001365609.1; = p.S692= on NM_018014.4) | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs146556401; called by muse, mutect2
- DNPEP | c.300C>T p.L100= | Silent (SNP) | VAF 13/277 reads (5%) | called by muse, mutect2
- FMN2 | c.3966C>G p.S1322= | Silent (SNP) | VAF 17/291 reads (6%) | called by muse, mutect2
- GLI2 | c.84G>T p.P28= | Silent (SNP) | VAF 24/348 reads (7%) | catalogued as rs377702863; called by muse, mutect2
- HTR4 | c.462T>C p.F154= | Silent (SNP) | VAF 16/323 reads (5%) | called by muse, mutect2
- KCNH6 | c.966C>G p.T322= | Silent (SNP) | VAF 21/460 reads (5%) | called by muse, mutect2
- KIF26A | c.1557A>T p.S519= | Silent (SNP) | VAF 23/269 reads (9%) | called by muse, mutect2
- KRT31 | c.561G>T p.L187= | Silent (SNP) | VAF 11/228 reads (5%) | called by muse, mutect2
- LRP1B | c.2340C>A p.P780= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- LRRC4C | c.960C>A p.A320= | Silent (SNP) | VAF 13/261 reads (5%) | called by muse, mutect2
- NOD1 | c.1182C>T p.C394= | Silent (SNP) | VAF 12/319 reads (4%) | called by muse, mutect2
- OPTC | c.324C>G p.T108= | Silent (SNP) | VAF 46/1040 reads (4%) | called by muse, mutect2
- PCDH8 | c.1266C>A p.G422= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs773081725; called by mutect2, varscan2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 20/688 reads (3%) | catalogued as COSV50858046; called by muse, mutect2
- PCDHB7 | c.1563C>T p.Y521= | Silent (SNP) | VAF 28/940 reads (3%) | catalogued as rs781837590, COSV50806337, COSV50823869; called by muse, mutect2
- S100A13 | c.249G>T p.L83= | Silent (SNP) | VAF 30/338 reads (9%) | called by muse, mutect2
- TJP1 | c.3726A>G p.K1242= | Silent (SNP) | VAF 20/476 reads (4%) | called by muse, mutect2
- TRPM6 | c.6066A>G p.L2022= | Silent (SNP) | VAF 29/443 reads (7%) | called by muse, mutect2
- YTHDF1 | c.303C>T p.H101= | Silent (SNP) | VAF 15/378 reads (4%) | catalogued as rs1480161354, COSV64833655; called by muse, mutect2
- ALKAL2 | c.*17C>A | 3'UTR (SNP) | VAF 11/341 reads (3%) | called by muse, mutect2
- AP000769.5 | chr11:65500516 G>A | 5'Flank (SNP) | VAF 20/566 reads (4%) | catalogued as rs958771941; called by muse, mutect2
- CNPY1 | c.241+35G>T | Intron (SNP) | VAF 28/494 reads (6%) | called by muse, mutect2
- HSP90B3P | n.1201G>A | RNA (SNP) | VAF 32/420 reads (8%) | called by muse, mutect2
- NTRK2 | c.-37C>A | 5'UTR (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- RGPD4 | c.-39G>T | 5'UTR (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
